Somatic mutation profile of tumor specimen TCGA-2G-AAH3-01A (aliquot TCGA-2G-AAH3-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAH3, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 20.5 years (7,474 days).
Specimen TCGA-2G-AAH3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 893350f7-3bcc-4c87-8274-2f14b5e57179.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAH3-10A (Blood Derived Normal), aliquot TCGA-2G-AAH3-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcbdf4e2-6494-401a-94de-9413577b3e12

The open-access MAF lists 31 somatic variants for this specimen: 24 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Intron 4, Nonsense Mutation 3, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2485G>C p.A829P | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1057519713, COSV55414160; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BAHD1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 32/146 reads (22%) | catalogued as COSV101346783; called by muse, mutect2, varscan2
- CCDC178 | c.770C>G p.A257G | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55787129; called by muse, mutect2, varscan2
- DDX3X | c.1421G>C p.R474P (on ENST00000399959; = p.R475P on NM_001356.5) | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV67863186; called by muse, mutect2
- EMC9 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as COSV52824214; called by muse, mutect2, varscan2
- ERICH3 | c.2626C>G p.P876A | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV58620657; called by muse, mutect2, varscan2
- LRFN2 | c.1423G>T p.A475S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0.028); catalogued as rs776145223; called by muse, mutect2, varscan2
- MAN2C1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.07); catalogued as COSV99145347; called by mutect2, varscan2
- NCOA4 | c.1635G>T p.K545N | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs782501366; called by muse, mutect2
- PBOV1 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.16); catalogued as rs756876603; called by muse, mutect2, varscan2
- ATP8A2 | c.3113G>A p.W1038* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- BAHD1 | c.1020G>T p.Q340H | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CDKN3 | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- KPNA7 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- LRBA | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRTM3 | c.190T>A p.L64I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGI2 | c.3561G>C p.R1187S | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAP1B | c.542C>G p.A181G | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MSX2 | c.581G>C p.R194T | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NASP | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP62 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2
- UBE2NL | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- VCAM1 | c.203A>T p.N68I | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VPS16 | c.1416C>G p.Y472* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | called by muse, mutect2, varscan2
- EARS2 | c.1233C>T p.C411= | Silent (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- TENM1 | c.4419C>T p.C1473= | Silent (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- AK9 | c.3633+13del | Intron (DEL) | VAF 7/78 reads (9%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- CCDC18 | c.-3+346G>A | Intron (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- GDF1 | c.-234C>G | 5'UTR (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- HSPD1 | c.428-20G>A | Intron (SNP) | VAF 65/423 reads (15%) | called by muse, mutect2, varscan2
- NETO1 | c.29-362dup | Intron (INS) | VAF 32/126 reads (25%) | called by mutect2, varscan2
